Surgical pathology report (de-identified scan), TCGA case TCGA-95-7947, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Emory, specimen TCGA-95-7947-01A (Primary Tumor).

[page 1 of 5]
Anat Path Reports

[REDACTED]

* Final Report *

Document Type: Anat Path Reports
Document Date: [REDACTED]
Document Status: Auth (Verified)
Document Title: Histology
Encounter info: [REDACTED]

* Final Report *

APRPT (Verified)

Patient Name:	[REDACTED]	Acc #:	[REDACTED]
MRN:	[REDACTED]	DOB:	[REDACTED]
Location:	[REDACTED]	Gender:	M
Client:	[REDACTED]	Collected:	[REDACTED]
Submitting	[REDACTED]	Received:	[REDACTED]
Phys:	[REDACTED]	Reported:	[REDACTED]

Final Surgical Pathology Report

Final Pathologic Diagnosis

- A. LUNG, LEFT UPPER LOBE, WEDGE RESECTION, A1FS:
- ADENOCARCINOMA, MIXED SUBTYPE, WITH ACINAR, PAPILLARY AND MICROPAPILLARY PATTERNS OF GROWTH.
THE CARCINOMA IS MODERATELY DIFFERENTIATED AND MEASURES 1.5 X 1.1 X 0.7 CM.
- ANGIOLYMPHATIC INVASION IDENTIFIED.
- NO VISCERAL PLEURAL INVASION IS IDENTIFIED.
- SURGICAL PARENCHYMAL MARGIN IS NEGATIVE FOR CARCINOMA.
- SEE SYNOPTIC REPORT.
- B. LYMPH NODES, #6, EXCISION, B1FS:
- FIVE LYMPH NODE FRGAMENTS, NEGATIVE FOR METASTATIC CARCINOMA (0/5).
- PARTIALLY CALCIFIED, FIBROTIC NODULES, NEGATIVE FOR CARCINOMA.
- C. LYMPH NODES, #7, EXCISION, C1FS:
- THREE LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/3).

Printed by: [REDACTED]
Printed on: [REDACTED]

Page 1 of 5
(Continued)

[page 2 of 5]
Anat Path Reports

* Final Report *

- D. **LYMPH NODE, #9, EXCISION, D1FS:**
- ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

- E. **LYMPH NODE, 10L, EXCISION, E1FS:**
- ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

- F. **LUNG, LEFT UPPER LOBE, MEDIAL, WEDGE RESECTION:**
- LUNG WITH BULLOUS EMPHYSEMATOUS CHANGES.
- NEGATIVE FOR CARCINOMA.

Comment

Immunohistochemical and special stains (all on block A3):

- CK7 ----- positive
- CK20 ----- negative
- TTF1 ----- positive
- Napsin A ----- negative
- Pax 8 ----- negative
- Mucicarmine ----- positive (focal)

This staining profile is compatible with a lung primary.

Synoptic Worksheet

A. Wedge excision left upper lobe:	
Specimen:	Lung
Procedure:	Wedge resection
Specimen Integrity:	Intact
Specimen Laterality:	Left
Tumor Site:	Upper lobe
Tumor Focality:	Unifocal
Histologic Type:	Adenocarcinoma, mixed subtype
Histologic Grade:	G2: Moderately differentiated
Tumor Size:	Greatest dimension: 1.5 cm
	Additional dimension: 1.1 cm
	Additional dimension: 0.7 cm
Visceral Pleura Invasion:	Not identified
Tumor Extension:	Not applicable
Bronchial Margin:	Involvement by invasive carcinoma not applicable
	Involvement by squamous cell carcinoma in situ (CIS) not applicable
Vascular Margin:	Not applicable

[page 3 of 5]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of [REDACTED] regarding patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

Anat Path Reports

* Final Report *

Parenchymal Margin:	Uninvolved by invasive carcinoma
Parietal Pleural Margin:	Not applicable
Chest Wall Margin:	Not applicable
Other Attached Tissue Margin:	Not applicable
Treatment Effect:	Not applicable
Lymph-Vascular Invasion:	Present
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT1a: Tumor 2 cm or less in greatest dimension, surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion more proximal than the lobar bronchus (ie, not in the main bronchus); or Superficial spreading tumor of any size with its invasive component limited to the bronchial wall, which may extend proximally to the main bronchus
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis Number of nodes examined cannot be determined
Distant Metastasis (pM):	Not applicable

Clinical History

Left VATS, upper lobe wedge, lymph node dissection. Laryngeal cancer.

Specimen(s) Received

A: Wedge excision left upper lobe
B: #6 Lymph node
C: #7 Lymph node
D: #9 Lymph node
E: 10 L lymph node
F: Medial wedge excision left upper lobe

Gross Description

Specimen A is received fresh for intraoperative consultation, labeled with the patient's name, medical record number and labeled "wedge excision, left upper lobe." It consists of a wedge of lung that weighs 23.8 gram and measures 10.8 x 4.7 x 2.2 cm. There is a firm, well-defined lesion (that was previously incised) that measures 1.5 x 1.1 x 0.7 cm. The lesion is 0.4 cm from the parenchymal margin and puckers the pleura. The remainder of the lung is unremarkable. The pleura is inked blue. Sections are submitted as follows: Dictated by [REDACTED]

A2,A3: Lesion pleura and margin
A4: Tumor in relation to surrounding lung
A5: Representative sections of uninvolved lung parenchyma

Specimen B is received fresh for intraoperative consultation, labeled with the patient's name, medical record number and as additionally "#6 lymph node for frozen." It consists of multiple pieces of soft tissue measuring in aggregate, 1.8 x 1.7 x 0.9 cm. The tissue is partially calcified. The non-calcified portions are submitted for frozen and the contents of the cryoblock are submitted in cassette "B1FS." The calcified tissue is sectioned and submitted for decal in its entirety in cassette "B2." Dictated by [REDACTED]

[page 4 of 5]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of [REDACTED] regarding patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

Anat Path Reports

* Final Report *

Specimen C is received fresh for intraoperative consultation, labeled with the patient's name, medical record number and "#7 lymph node." It consists of four pieces of soft tissue in aggregate measuring 1.5 x 0.2 x 0.1 cm. The specimen is entirely submitted for intraoperative consultation and transferred to cassette "C1FS." (Dictated by [REDACTED])

Specimen D is received fresh for intraoperative consultation, labeled with the patient's name, medical record number and "#9 lymph node." It consists of a fatty soft tissue fragment measuring 0.6 x 0.4 x 0.3 cm. The specimen is entirely submitted for intraoperative consultation and transferred to cassette "D1FS." (Dictated by [REDACTED])

Specimen E is received fresh for intraoperative consultation, labeled with the patient's name, medical record number and "10L lymph node." It consists of a soft tissue fragment measuring 0.6 x 0.5 x 0.4 cm. The fragment is entirely submitted for intraoperative consultation and transferred to cassette "E1FS." (Dictated by [REDACTED])

Specimen F is received in formalin, labeled with the patient's name, medical record number and additionally "medial wedge excision, left upper lobe." It consists of a wedge of lung that measures 8.1 x 2.0 x 2.0 cm and weighs 15 grams. There is a pleural bleb that measures 2.8 x 1.9 x 1.9 cm. The remainder of the lung is unremarkable. The parenchymal margin is inked green and the pleura is inked blue. Sections are submitted as follows: Dictated by [REDACTED]

F1: Section of bleb and normal lung parenchyma
F2: Normal lung parenchyma

Intraoperative Consult Diagnosis

A1FS: LUNG, LEFT UPPER LOBE (FROZEN SECTION): ADENOCARCINOMA.
Frozen section results were communicated to the surgical team and were repeated back by [REDACTED] on [REDACTED] in at [REDACTED] out at [REDACTED]

B1FS,B1TP: #6 LYMPH NODE (FROZEN SECTION AND TOUCH PREPARATION): NEGATIVE FOR CARCINOMA.
Frozen section results were communicated to the surgical team and were repeated back by [REDACTED] on [REDACTED] in at [REDACTED] out at [REDACTED]

C1FS: #7 LYMPH NODES (FROZEN SECTION): THREE LYMPH NODES NEGATIVE FOR CARCINOMA.
Frozen section results were communicated to the surgical team and were repeated back by [REDACTED] on [REDACTED] at [REDACTED] and start time [REDACTED]

D1FS: #9 LYMPH NODE (FROZEN SECTION): ONE LYMPH NODE NEGATIVE FOR CARCINOMA.
Frozen section results were communicated to the surgical team and were repeated back by [REDACTED] on [REDACTED] at [REDACTED] and start time [REDACTED]

E1FS: #10 LYMPH NODE (FROZEN SECTION): ONE LYMPH NODE NEGATIVE FOR CARCINOMA.
Frozen section results were communicated to the surgical team and were repeated back by [REDACTED] on [REDACTED] at [REDACTED] and start time [REDACTED]

Pathologist [REDACTED]

Printed by: [REDACTED]
Printed on: [REDACTED]

[page 5 of 5]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of [REDACTED] regarding patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

Anat Path Reports

* Final Report *

Microscopic Description

Microscopic examination performed.

ANALYTE SPECIFIC REAGENT (ASR) DISCLAIMER:

Some of the above tests may use Class I ASRs. These tests were developed and their performance characteristics determined by [REDACTED]. They have not been cleared or approved by the Federal Drug Administration (FDA). The FDA does not require these tests to go through premarket FDA review. These tests are used for clinical purposes, and should not be regarded as investigational or for research. [REDACTED] is certified under the Clinical Laboratory Improvement Amendments (CLIA) as qualified to perform high complexity clinical laboratory testing.

Printed by:
Printed on:

Source: NCI Genomic Data Commons file 05fc3749-a445-4f28-97c6-872b27de29f1 (TCGA-95-7947.003C68CB-72EA-44C9-80E3-F62224AB3EE2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).